Somatic mutation profile of tumor specimen TCGA-AC-A8OR-01A (aliquot TCGA-AC-A8OR-01A-21D-A41F-09) from TCGA case TCGA-AC-A8OR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.6 years (27,605 days).
Specimen TCGA-AC-A8OR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6c8c275-ce1c-42fd-a66d-2e7b0246ea1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A8OR-10A (Blood Derived Normal), aliquot TCGA-AC-A8OR-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e387e8a-3a41-4720-81f0-f8a80a8b17ae

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKAL1 | c.794G>T p.R265I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV99216476; called by muse, mutect2
- CDKL1 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV99367918; called by muse, mutect2
- CLIC6 | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100659326; called by muse, mutect2, varscan2
- COL2A1 | c.3327+1G>A p.X1109_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as CS160594, COSV100477508; called by muse, mutect2, varscan2
- CXXC5 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV100210823; called by muse, mutect2
- DMXL2 | c.2026A>T p.T676S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); catalogued as COSV99198599; called by muse, mutect2, varscan2
- DNAH1 | c.5096C>T p.A1699V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs954066157, COSV101327078; called by muse, mutect2, varscan2
- ELL | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99443768; called by muse, mutect2, varscan2
- FGFRL1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767226381, COSV99294856; called by muse, mutect2, varscan2
- GBP6 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100969698; called by muse, mutect2, varscan2
- NOL11 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475301, COSV99475308; called by muse, mutect2
- NOS1 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100501417; called by muse, varscan2
- POU4F1 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV101020602; called by muse, varscan2
- PTPRU | c.1283G>A p.G428D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as rs972529303, COSV100113732; called by muse, mutect2, varscan2
- SIPA1L1 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as rs1487966087, COSV100666076; called by muse, mutect2
- SLC15A1 | c.1880C>A p.A627D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919539; called by muse, mutect2
- SPAG5 | c.2019C>A p.S673R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100410868; called by muse, varscan2
- TELO2 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99248730; called by muse, mutect2
- THBS2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as rs202062355; called by muse, mutect2, varscan2
- TLR6 | c.2030A>T p.N677I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101126309; called by muse, mutect2, varscan2
- USP1 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772351967, COSV100375455; called by muse, mutect2, varscan2
- NRARP | c.10dup p.A4Gfs*209 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- SETD5 | c.893_897del p.I298Rfs*13 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- KIT | c.2295C>T p.D765= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1398046219, COSV99855337, COSV99855836; called by muse, mutect2
- KLF11 | c.87G>T p.R29= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1199072785, COSV100007912; called by muse, varscan2
- PPFIA3 | c.693C>T p.S231= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100495292; called by muse, mutect2, varscan2
- TG | c.2430A>G p.R810= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99603229; called by muse, mutect2, varscan2
- UAP1 | c.186A>G p.Q62= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99618079; called by muse, mutect2, varscan2
- ZNF697 | c.483C>A p.R161= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101360331; called by mutect2, varscan2
